Gene-level copy-number profile of tumor specimen TCGA-B6-A40B-01A from TCGA case TCGA-B6-A40B, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 76.1 years (27,811 days).
Specimen TCGA-B6-A40B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2da6a5d4-1759-4d0b-b023-cf9e2dabb8a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A40B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e73528ed-3e24-4e63-986d-be57cd651d9f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,359; copy number 2: 46,059; copy number 3: 6,136; copy number 4: 64; copy number 7: 158; copy number 8: 28; copy number 9: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A40B-01A-11D-A238-01): tumor purity 0.63, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 194 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,475,567–70,398,488, 28 genes, copy number 8: LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr11:97,878,475–100,358,885, 8 genes, copy number 9 (within-gene range 1–9): LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53.
- chr16:3,242,027–5,235,822, 94 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr16:5,260,686–5,366,688, 4 genes, copy number 7: AC074051.2, RPS3AP48, SNRPCP20, NPM1P3.
- chr16:9,753,404–10,182,928, 1 gene, copy number 7 (within-gene range 2–7): GRIN2A.
- chr16:10,033,684–11,828,845, 59 genes, copy number 7: AC133565.1, IMPDH1P11, AC022168.1, RN7SL493P, ATF7IP2, AC131649.1, AC131649.2, RNU6-633P, LINC01290, EMP2, AC027277.1, AC027277.2, TEKT5, AC007595.1, MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24, NUBP1, TVP23A, AC133065.2, AC133065.1, CIITA, DEXI, AC133065.3, CLEC16A, RPL7P46, AC007014.2, AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.

Autosomal genes at a single copy (total copy number 1): 7,359. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
